Somatic mutation profile of tumor specimen TARGET-10-PARMSP-09A (aliquot TARGET-10-PARMSP-09A-01D) from TARGET case TARGET-10-PARMSP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,555 days).
Specimen TARGET-10-PARMSP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa031cc-bb57-4ac5-8cda-5f911dafb298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMSP-10A (Blood Derived Normal), aliquot TARGET-10-PARMSP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1622a053-3769-4713-b2c9-e05e75a9c95e

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CARD10 | c.1129T>C p.Y377H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1322066454; called by muse, mutect2, varscan2
- DRD5 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV58579413; called by muse, mutect2
- IQSEC3 | c.1016G>A p.R339H (on ENST00000538872 / NM_001170738.2; = p.R36H on NM_015232.1) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs896683790; called by muse, mutect2, varscan2
- NTN3 | c.1384_1386del p.K462del | In Frame Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs770775622; called by pindel, varscan2
- SLITRK3 | c.1878G>T p.Q626H | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV53849628; called by muse, mutect2
- ZNF597 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100071941; called by muse, mutect2
- CARNMT1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCNB1 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- CROCC | c.3167C>A p.A1056E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- DLG5 | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.046); called by muse, mutect2
- GALNT15 | c.1507C>A p.P503T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2
- GRID2 | c.2490C>G p.S830R | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2
- HLA-DQA2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PLCH2 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- QSER1 | c.1963del p.D656Ifs*8 (on ENST00000399302; = p.D785Ifs*8 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- ELF5 | c.744G>A p.R248= (on ENST00000312319 / NM_198381.2; = p.R238= on NM_001422.4) | Silent (SNP) | VAF 74/150 reads (49%) | called by muse, mutect2, varscan2
- SGSH | c.325C>T p.L109= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs930899199; called by muse, mutect2, varscan2
- SLC35A2 | c.1095C>T p.P365= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1458590457, COSV54430352; called by muse, mutect2
- TXNRD3 | c.264T>C p.S88= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- TYW1B | c.1476C>T p.F492= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-14414C>T | Intron (SNP) | VAF 11/124 reads (9%) | catalogued as rs971103743, COSV52548661; called by muse, mutect2
